Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LL, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LL-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries (
- 2: SP: Left Jackson's lymph node
- 3: SP: Left external iliac lymph node
- 4: SP: Left hypogastric lymph node (
- 5: SP: Left obturator lymph node (
- 6: SP: Left common iliac lymph node (
- 7: SP: Right external iliac lymph node (
- 8: SP: Right hypogastric lymph node (
- 9: SP: Right obturator lymph node (
- 10: SP: Right common iliac lymph node (
- 11: SP: Right para-aortic lymph node
- 12: SP: Left para-aortic lymph node (

adenocarcinoma, endometrioid, nos 8380/3
Site: endometrium C54.1

h
5/11

DIAGNOSIS:

- 1) UTERUS, CERVIX, BILATERAL OVARIES AND FALLOPIAN TUBES; TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, WITH FOCAL SQUAMOUS DIFFERENTIATION.
- THE TUMOR PRESENTS AS A 4.0 CM POLYPOID LESION IN THE ENDOMETRIAL CAVITY, FIGO GRADE 1 (≤ 6% SOLID GROWTH), NUCLEAR GRADE 2-3.
- THE TUMOR INVADERS TO ≤ HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 1.0 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 13.0 MM.
- THE TUMOR INVOLVES ADENOMYOSIS.
- ENDOCERVICAL INVOLVEMENT IS PRESENT IN THE MUCOSA.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: COMPLEX HYPERPLASIA WITH ATYPIA.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ADENOMYOSIS.
- THE RIGHT AND LEFT OVARIES SHOW ENDOSALPINGIOSIS.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.

- 2) LYMPH NODE, LEFT EXCISION:

** Continued on next page **

[page 2 of 2]
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODES, LEFT HYPOGASTRIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 5) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 6) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 7) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 8) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 9) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 10) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 11) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 12) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 30424488-2200-43c1-972e-f9b599d961f0 (TCGA-AP-A0LL.B4A6F5DE-E477-48FD-ADA1-EAE436FBC576.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).